Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A72U, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A72U-01A (Primary Tumor).

ICD-O-3
Oligodendroglioma, grade III
9451/3
Site (R) Brain, supratentorial NOS
C71.0
JW 8/15/13

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by soft gray-pink pieces from right parietal lobe

Microscopic description:

Received material is represented mainly by brain tissue consistent with anaplastic oligodendroglioma with foci of necrosis.

Final diagnosis: Anaplastic oligodendroglioma: Grade III

Confidential

Source: NCI Genomic Data Commons file 89c27ae2-73b3-4c9e-81bd-58507415c723 (TCGA-P5-A72U.5C661E0D-6AC0-47DD-851F-8ED068BEF14D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).